Somatic mutation profile of tumor specimen TCGA-04-1516-01A (aliquot TCGA-04-1516-01A-01D-1526-09) from TCGA case TCGA-04-1516, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 48.6 years (17,768 days).
Specimen TCGA-04-1516-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8347750-96a0-47f0-8eec-46a612a741d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1516-11B (Solid Tissue Normal), aliquot TCGA-04-1516-11B-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fbb268f-3d2b-425b-b736-f3b967f807de

The open-access MAF lists 52 somatic variants for this specimen: 45 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 37, Silent 7, Frame Shift Del 3, Splice Site 3, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA6 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762344231, COSV52645942; called by muse, varscan2
- ACAD11 | c.841+1G>A p.X281_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | catalogued as COSV53902226; called by mutect2, varscan2
- ADAMTS17 | c.2630G>T p.C877F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51495388; called by muse, mutect2, varscan2
- ARC | c.760T>A p.W254R | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63079917; called by muse, mutect2, varscan2
- ARID1B | c.6202C>T p.L2068F | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99269312; called by muse, mutect2, varscan2
- BBX | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs76764171; called by muse, mutect2, varscan2
- BRINP3 | c.2149G>A p.G717S | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as rs1243524797, COSV100819196, COSV66543104; called by muse, mutect2, varscan2
- CCDC141 | c.2421G>C p.E807D | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV55383605; called by muse, mutect2, varscan2
- COPB1 | c.447C>G p.S149R | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51451415; called by muse, varscan2
- CPA3 | c.1206G>A p.M402I | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV56044955, COSV56047565; called by mutect2, varscan2
- CPT1B | c.1340A>G p.N447S | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100376666; called by muse, mutect2
- CROCC | c.2647G>C p.V883L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65015208; called by muse, mutect2, varscan2
- CSRNP3 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as COSV58786604; called by muse, mutect2, varscan2
- CYLC2 | c.1043A>T p.K348M | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); catalogued as COSV66339912; called by muse, mutect2, varscan2
- DAO | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99948617; called by muse, mutect2
- DYNC1H1 | c.7909C>G p.H2637D | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV64143629; called by muse, mutect2, varscan2
- EGFLAM | c.188G>C p.S63T | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV59311834, COSV59319609; called by muse, mutect2, varscan2
- HOXA1 | c.431A>T p.H144L | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV56067956; called by muse, mutect2, varscan2
- HSPB1 | c.29T>A p.L10H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs772216758, COSV50349812; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JUP | c.1544A>C p.H515P | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV60280098; called by muse, mutect2, varscan2
- LRP12 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV52635326; called by muse, mutect2, varscan2
- MED12L | c.2090C>G p.S697C | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56399890; called by muse, mutect2, varscan2
- MME | c.653A>C p.H218P | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV64711327; called by muse, mutect2, varscan2
- MYH4 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV55127475; called by muse, mutect2, varscan2
- NME7 | c.363del p.K122Nfs*4 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | catalogued as COSV63167132; called by mutect2, pindel, varscan2
- NPRL2 | c.720+1G>A p.X240_splice | Splice Site (SNP) | VAF 16/171 reads (9%) | catalogued as COSV99205067; called by muse, mutect2
- OR2D3 | c.925A>G p.R309G | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53495355; called by muse, mutect2, varscan2
- OR5D18 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759145981, COSV61738861; called by muse, mutect2, varscan2
- PLK1 | c.1467C>G p.H489Q | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV55624556; called by muse, mutect2, varscan2
- PODNL1 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54310100; called by muse, mutect2, varscan2
- PRRX2 | c.557A>C p.Q186P | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV65243530; called by muse, mutect2, varscan2
- RMDN1 | c.356G>C p.W119S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99547662; called by muse, mutect2, varscan2
- SKIV2L | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753846268, COSV64814600; called by muse, varscan2
- SLC1A3 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 49/214 reads (23%) | catalogued as COSV54320981; called by muse, mutect2, varscan2
- SLC6A2 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54915951, COSV99573891; called by muse, mutect2
- UNC119 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV56380193; called by muse, mutect2, varscan2
- XPNPEP2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100941209; called by muse, mutect2
- XRN1 | c.2624A>T p.D875V | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV53818969; called by muse, varscan2
- ZKSCAN2 | c.677A>G p.Q226R | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV60159083; called by muse, mutect2, varscan2
- ZNF212 | c.930G>C p.K310N | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV60025235, COSV60026368; called by muse, mutect2, varscan2
- ZNF681 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV101267474, COSV68073482, COSV68074913; called by muse, mutect2
- ALK | c.1508_1537del p.V503_Q512del | In Frame Del (DEL) | VAF 65/257 reads (25%) | called by mutect2, pindel
- FEM1C | c.999_1002delinsACA p.P335Lfs*41 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by pindel, varscan2*
- KCNMB4 | c.335_336+22del p.X112_splice | Splice Site (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel
- OR2M5 | c.850_862del p.M284Sfs*10 | Frame Shift Del (DEL) | VAF 19/179 reads (11%) | called by mutect2, pindel
- ARHGAP6 | c.2250A>T p.G750= (on ENST00000337414 / NM_013427.3; = p.G547= on NM_013423.3) | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV57304289; called by muse, mutect2, varscan2
- CAD | c.6129C>T p.I2043= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV53032606; called by muse, mutect2, varscan2
- FTCD | c.282C>A p.I94= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99385091; called by muse, mutect2
- GDF15 | c.159C>T p.F53= | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as COSV99416159; called by muse, mutect2
- SETBP1 | c.1794C>G p.V598= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV56335858, COSV99953374; called by muse, mutect2
- TMEM154 | c.12C>G p.P4= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV58592458; called by muse, mutect2, varscan2
- ZNF585B | c.825C>T p.C275= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as rs778576945, COSV100459462; called by muse, mutect2
